Somatic mutation profile of tumor specimen TCGA-FD-A6TF-01A (aliquot TCGA-FD-A6TF-01A-52D-A32B-08) from TCGA case TCGA-FD-A6TF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,317 days).
Specimen TCGA-FD-A6TF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab613b36-c1cb-45b6-9794-809b595d87aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TF-10A (Blood Derived Normal), aliquot TCGA-FD-A6TF-10A-21D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e3a7482-2792-4625-819a-93e12be9923f

The open-access MAF lists 163 somatic variants for this specimen: 120 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 38, Nonsense Mutation 9, Splice Site 5, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NAA10 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as rs587780563, CM129317, COSV64169392; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- ACCS | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55457826, COSV99772861; called by muse, mutect2, varscan2
- ADAMTS13 | c.1730C>A p.T577N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.728); catalogued as COSV63020952; called by muse, mutect2, varscan2
- ADCY2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100603825; called by muse, mutect2, varscan2
- AFAP1L2 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.346); catalogued as COSV58413992; called by muse, mutect2
- AGXT | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56753753; called by muse, mutect2, varscan2
- AHI1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99663557; called by muse, mutect2, varscan2
- ANKFY1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV58916757; called by muse, mutect2, varscan2
- ANKRD34B | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58613782, COSV58613848; called by muse, mutect2
- APCS | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.389); catalogued as COSV54817841, COSV54817863; called by muse, mutect2
- APOBEC3G | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746521588, COSV68470248; called by muse, mutect2, varscan2
- ARHGEF40 | c.3502C>T p.L1168F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1244833807, COSV53879674; called by muse, mutect2, varscan2
- ATG7 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.642); catalogued as rs968962192, COSV61612074; called by muse, varscan2
- ATP8B4 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as rs745703865, COSV99467115; called by muse, mutect2, varscan2
- BARD1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as rs148760338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.1923G>C p.L641F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59990481; called by muse, mutect2, varscan2
- BMP6 | c.1157A>T p.N386I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV51664052; called by muse, mutect2, varscan2
- BRD4 | c.2450T>G p.F817C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99651315; called by muse, mutect2
- C1orf141 | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV63992037, COSV63992499; called by muse, mutect2
- CASK | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV59365268; called by muse, mutect2, varscan2
- CCDC15 | c.1982A>G p.Y661C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs761598183, COSV100777049; called by muse, varscan2
- CDK10 | c.950G>C p.C317S (on ENST00000353379 / NM_052988.5; = p.C246S on NM_052987.4) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV57046568; called by muse, mutect2, varscan2
- CENPF | c.8512G>A p.E2838K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as COSV65274260; called by muse, mutect2, varscan2
- CEP57 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57688059; called by muse, mutect2, varscan2
- CEP85L | c.466T>A p.W156R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821385; called by muse, mutect2
- CFAP46 | c.6569C>T p.P2190L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV54151254; called by muse, mutect2, varscan2
- CLCNKA | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370236498; called by muse, mutect2, varscan2
- CMSS1 | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV70436798; called by muse, mutect2, varscan2
- COL5A3 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs367847974; called by muse, mutect2, varscan2
- CTTNBP2 | c.4556G>C p.R1519T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs568993434, COSV50396256; called by muse, mutect2, varscan2
- DNAJC14 | c.1971G>C p.Q657H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54478184, COSV54478688; called by muse, mutect2, varscan2
- DPY19L3 | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60475824; called by muse, mutect2, varscan2
- ESM1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101195716, COSV67318511; called by muse, mutect2, varscan2
- FAAH | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV54543787; called by muse, mutect2, varscan2
- FEM1A | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54163556; called by muse, mutect2, varscan2
- GBP3 | c.1567C>G p.Q523E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV52518123; called by muse, mutect2, varscan2
- GDPD1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52381488; called by muse, mutect2
- GIN1 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67536744, COSV67536949; called by muse, mutect2, varscan2
- HCAR2 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.634); catalogued as COSV61024761; called by muse, mutect2, varscan2
- HERC1 | c.11324C>G p.S3775C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101497023, COSV71247308; called by muse, mutect2
- HFE | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs1450662478, COSV58512988; called by muse, mutect2, varscan2
- HOXA7 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV54217325; called by muse, mutect2, varscan2
- HRH1 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV67955102, COSV67955242, COSV67955349; called by muse, mutect2, varscan2
- HSBP1 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV71139033; called by muse, mutect2, varscan2
- IDH3A | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100211002; called by muse, mutect2, varscan2
- IGF1R | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV51270428; called by muse, mutect2, varscan2
- IRF4 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66704969; called by muse, mutect2, varscan2
- KCNT1 | c.2740C>T p.R914C (on ENST00000488444; = p.R933C on NM_020822.3) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs150395210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIZ | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99852341; called by muse, mutect2
- KNTC1 | c.5109C>G p.F1703L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV100338715; called by muse, mutect2
- KPRP | c.603C>G p.C201W | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV64221449; called by muse, mutect2
- LOXL3 | c.1648C>G p.H550D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1380779977, COSV51207039; called by muse, mutect2, varscan2
- LTBP1 | c.3482-1G>C p.X1161_splice (on ENST00000404816 / NM_206943.4; = p.X835_splice on NM_000627.4) | Splice Site (SNP) | VAF 14/96 reads (15%) | catalogued as COSV55378677, COSV99698705; called by muse, mutect2
- MAFB | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV64826524; called by muse, mutect2, varscan2
- MAGEC1 | c.2532G>C p.K844N | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV53571438; called by muse, mutect2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MAN2C1 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs148467582; called by muse, mutect2, varscan2
- MCL1 | c.587C>G p.T196R | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1398107858, COSV57190228; called by muse, mutect2, varscan2
- MST1R | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56567762; called by muse, mutect2, varscan2
- MYO1F | c.772-1G>C p.X258_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as COSV57794112; called by muse, mutect2, varscan2
- NASP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63112685; called by muse, mutect2, varscan2
- NCAM1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57514587; called by muse, mutect2, varscan2
- NLGN3 | c.1354G>C p.E452Q (on ENST00000358741 / NM_181303.2; = p.E432Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV62442675; called by muse, mutect2
- NUF2 | c.1274A>C p.N425T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54843367; called by muse, mutect2, varscan2
- NUP205 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1450907830, COSV53657821; called by muse, mutect2, varscan2
- OR14J1 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65845620; called by muse, mutect2, varscan2
- OR1K1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs190021761; called by muse, mutect2, varscan2
- OR4D9 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs751950581, COSV61434479; called by muse, mutect2, varscan2
- PARD6B | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as rs774219054, COSV65404352; called by muse, mutect2, varscan2
- PER1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1185884822, COSV57918854; called by muse, mutect2, varscan2
- PLEKHH3 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs745681741, COSV52217346; called by muse, mutect2, varscan2
- PPM1D | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as rs541664685, COSV59955295; called by muse, mutect2, varscan2
- PRDM8 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as rs748579277, COSV60202383, COSV60203272; called by muse, varscan2
- PRPS1L1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs1265642318, COSV72649874; called by muse, mutect2, varscan2
- PTPN12 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs1218679746, COSV50356525; called by muse, mutect2, varscan2
- PYGM | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV51216101; called by muse, mutect2, varscan2
- RAD9A | c.728C>G p.P243R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57236524; called by muse, mutect2, varscan2
- RB1 | c.1128-1G>C p.X376_splice | Splice Site (SNP) | VAF 34/100 reads (34%) | catalogued as CS0910369, COSV57294096, COSV57303787; called by muse, mutect2, varscan2
- RBBP6 | c.4060A>G p.T1354A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1246109996, COSV60504525; called by muse, mutect2, varscan2
- RCOR2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV56849907, COSV56850689; called by muse, mutect2, varscan2
- RMND1 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV60550430; called by muse, varscan2
- SLC17A2 | c.626G>A p.W209* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99614879; called by muse, mutect2, varscan2
- SLC22A11 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs774475171, COSV57252790; called by muse, mutect2, varscan2
- SLC47A1 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54500547; called by muse, mutect2, varscan2
- SLC5A3 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV62969119; called by muse, mutect2, varscan2
- SLCO6A1 | c.4T>A p.F2I | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV65808647; called by muse, mutect2, varscan2
- SUCO | c.3058C>G p.L1020V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55264234; called by muse, mutect2, varscan2
- TMPO | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs781585188, COSV54122739; called by muse, mutect2, varscan2
- TOX2 | c.738G>C p.K246N (on ENST00000358131 / NM_001098798.2; = p.K195N on NM_032883.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100363606, COSV100364544; called by muse, mutect2
- TRAPPC12 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV100160888; called by muse, mutect2
- TRHR | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV61233613; called by muse, mutect2, varscan2
- TRIM71 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1183435271, COSV67470690; called by muse, mutect2, varscan2
- TRIO | c.6466G>T p.G2156W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710849; called by muse, mutect2
- TRPM1 | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 75/293 reads (26%) | catalogued as rs778880898, COSV56630744; called by muse, mutect2, varscan2
- TRPV5 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV54684941; called by muse, mutect2
- TRRAP | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV62842867; called by muse, mutect2
- TRRAP | c.10057G>C p.E3353Q (on ENST00000359863 / NM_001244580.1; = p.E3324Q on NM_003496.3) | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62842871; called by muse, mutect2, varscan2
- TSC1 | c.1863C>G p.I621M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as COSV53766160; called by muse, mutect2, varscan2
- TSPYL1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63994035, COSV63994239; called by muse, mutect2, varscan2
- TTN | c.14380G>C p.D4794H (on ENST00000591111; = p.D3867H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | PolyPhen possibly damaging (0.847); catalogued as COSV59997180, COSV60060818; called by muse, mutect2, varscan2
- TUT4 | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938147787, COSV57112658; called by muse, mutect2, varscan2
- UBXN7 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV56355238; called by muse, mutect2
- USP28 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV50159383; called by muse, mutect2, varscan2
- WAC | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 53/124 reads (43%) | catalogued as COSV100611171; called by muse, mutect2, varscan2
- ZMIZ2 | c.2509C>T p.H837Y | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54807316; called by muse, mutect2
- ZNF311 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | catalogued as rs750040086, COSV101014248; called by muse, mutect2
- ZNF674 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV70378932; called by muse, mutect2
- ZNF761 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV61888091; called by muse, mutect2, varscan2
- ZNF780B | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.38); catalogued as COSV55463582; called by muse, mutect2, varscan2
- ZNF804A | c.386+1G>T p.X129_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56445015; called by muse, mutect2, varscan2
- ZNF99 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV68055501; called by muse, mutect2, varscan2
- ZSCAN21 | c.593-1G>C p.X198_splice | Splice Site (SNP) | VAF 13/67 reads (19%) | catalogued as COSV52850195; called by muse, mutect2, varscan2
- ABCA12 | c.1563dup p.Q522Afs*23 (on ENST00000272895 / NM_173076.3; = p.Q204Afs*23 on NM_015657.3) | Frame Shift Ins (INS) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.1091del p.P364Qfs*5 | Frame Shift Del (DEL) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
- MLLT3 | c.125_149del p.S42Kfs*24 | Frame Shift Del (DEL) | VAF 20/180 reads (11%) | called by mutect2, pindel
- MUC4 | c.2314del p.H772Ifs*88 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- SPAG1 | c.2109dup p.L704Tfs*10 | Frame Shift Ins (INS) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- ANK2 | c.10899C>T p.L3633= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1460849721, COSV52156717, COSV52160599; called by muse, mutect2, varscan2
- ASZ1 | c.375G>A p.E125= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV52912497; called by muse, mutect2, varscan2
- ATP8B1 | c.1254C>T p.F418= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV52174991; called by muse, mutect2
- CAVIN1 | c.939C>T p.T313= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs780026361, COSV63811685; called by muse, mutect2, varscan2
- CENPA | c.339C>T p.T113= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV51982609; called by muse, mutect2
- CHST8 | c.504G>A p.R168= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV52858171, COSV99380922; called by muse, mutect2, varscan2
- CSMD2 | c.7869C>T p.I2623= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV53903150; called by muse, mutect2, varscan2
- CTNS | c.645C>T p.L215= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV50440270; called by muse, mutect2, varscan2
- DCC | c.3825G>A p.P1275= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs753536689, COSV71426260; called by muse, mutect2, varscan2
- ELAVL3 | c.6C>T p.V2= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53402621; called by muse, mutect2, varscan2
- FAM168B | c.408C>T p.I136= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs553389316, COSV66303942, COSV66304087; called by muse, mutect2, varscan2
- FAM47A | c.2235C>T p.S745= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV60494333, COSV60495887; called by muse, mutect2, varscan2
- FRMPD4 | c.3378C>G p.A1126= | Silent (SNP) | VAF 28/278 reads (10%) | catalogued as COSV66213810; called by muse, mutect2, varscan2
- GALNT17 | c.1536G>A p.L512= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV61158081; called by muse, mutect2, varscan2
- GPR62 | c.888C>G p.P296= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1034765061, COSV59055369; called by muse, mutect2
- IQGAP2 | c.516A>G p.V172= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1339369117, COSV57172029; called by muse, mutect2, varscan2
- ITGAD | c.58C>T p.L20= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV66757634; called by muse, mutect2, varscan2
- KLHDC7B | c.1194C>G p.L398= (on ENST00000395676; = p.L1039= on NM_138433.5) | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV67464481; called by muse, mutect2, varscan2
- LRIT1 | c.54G>A p.Q18= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100812967; called by muse, mutect2, varscan2
- MAFB | c.711C>T p.I237= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100965034, COSV100965069; called by muse, mutect2
- MAGEB6B | c.765G>A p.T255= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1194663441, COSV69689621; called by muse, mutect2, varscan2
- MSH5 | c.531C>T p.L177= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as COSV65209372; called by muse, mutect2, varscan2
- MYH3 | c.5739C>T p.I1913= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1011279441, COSV56863640; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10X1 | c.729G>A p.R243= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV63767233; called by muse, mutect2, varscan2
- OR3A3 | c.753C>G p.G251= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs1346099757, COSV52167282, COSV99351607; called by muse, mutect2, varscan2
- OXSR1 | c.1488T>C p.N496= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV61258276; called by muse, mutect2
- PIGW | c.240C>A p.L80= | Silent (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- PLCG2 | c.2883G>A p.T961= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1039745519, COSV63868826; called by muse, mutect2, varscan2
- PPP4R3B | c.30C>T p.V10= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs770660217, COSV55403730; called by muse, varscan2
- PRPH | c.663G>A p.L221= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57678400; called by muse, mutect2, varscan2
- SHANK1 | c.747C>T p.T249= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs772735940, COSV53247970; called by muse, mutect2, varscan2
- SMC1B | c.1458T>C p.N486= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV62529526; called by muse, mutect2, varscan2
- TGFBR3 | c.1947G>A p.R649= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV53024510; called by muse, mutect2, varscan2
- TTLL13P | c.396C>G p.V132= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV60037044; called by muse, mutect2, varscan2
- VENTX | c.666G>A p.G222= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1399366800, COSV100384135; called by muse, mutect2
- ZNF248 | c.1272C>G p.T424= | Silent (SNP) | VAF 13/294 reads (4%) | catalogued as COSV61997508; called by muse, mutect2
- ZNF430 | c.696T>C p.S232= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55108970; called by muse, mutect2, varscan2
- ZNF536 | c.3651C>T p.P1217= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs201688634, COSV100835119, COSV62822661; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823013 G>A | 5'Flank (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846389 G>C | 5'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- IGF2BP2 | c.240-18124G>A | Intron (SNP) | VAF 30/126 reads (24%) | catalogued as COSV56211447; called by muse, mutect2, varscan2
- MIR890 | n.26C>T | RNA (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- RPL13A | c.88+48C>T | Intron (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99201348; called by muse, mutect2
